Surgical pathology report (de-identified scan), TCGA case TCGA-DH-5143, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site University of Florida, specimen TCGA-DH-5143-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN(S) SUBMITTED/ PROCEDURES ORDERED:

CLINICAL HISTORY: [REDACTED] old male with seizure history for [REDACTED]. Headache, visual problems. MRI reveals left anterior lateral temporal lobe lesion.

GROSS DESCRIPTION: Received the following specimen in the Department of Pathology, labeled with the patient's name and [REDACTED]

A. Brain tumor

B. Brain tumor

A. The specimen is received fresh designated "brain tumor" and consists of a 5.2 x 3.5 x 1.6 cm portion of cortical gray matter and some cortical white matter with a 3.2 x 3.0 x 1.4 cm homogeneous mass at one edge. The gray-white junction in the other portion of the specimen is smudged and obscured. The portion is submitted for frozen section. The frozen section diagnosis is "Diffuse low grade glioma" by [REDACTED]. The frozen section tissue is submitted entirely for permanent processing in cassette FSA1, and additional sections are submitted in cassettes A2 through A6. A portion of the tissue is also submitted to the [REDACTED].

B. The specimen is received fresh designated "brain tumor" and consists of a 2.2 x 1.5 x 1.0 cm portion of gray-white to beige soft tissue with possible white matter visible at one edge. The specimen is submitted in cassettes B1 and B2.

DIAGNOSIS:

A. "Brain tumor":

Anaplastic mixed glioma oligoastrocytoma (WHO Grade III)

B. "Brain tumor":

Anaplastic mixed glioma oligoastrocytoma (WHO Grade III)

COMMENT: This tumor consists primarily of large areas of diffuse low-grade glioma with primarily astrocytic features but also containing oligodendrogliomatous areas. There are a few areas of increased cellularity in which there are increased mitoses. The Ki-67 labeling index is 5-10% in such areas while the remainder of the tumor shows less nuclear labeling. P53 protein immunoreactivity is noted in slightly greater than 50% of tumor cells. GFAP shows variable reactivity throughout the tumor. These results support the diagnosis.

"I, or my qualified designee, have performed the gross examination and description and I have personally reviewed the gross description and specimen preparations referenced herein, and have personally issued this report."

Resident/Prosector/Pathologist: [REDACTED]

Note: Test systems have been developed and their performance characteristics determined by [REDACTED]. Some tests have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance is not necessary. These tests are used for clinical purposes and should not be regarded as investigational or for research. This laboratory is certified under the

[page 2 of 2]
Clinical Laboratory Improvement Amendments of [REDACTED] as qualified to perform high complexity clinical laboratory testing.

[REDACTED]
Pathologist

Electronically signed [REDACTED]

ADDENDUM:

CHROMOSOMES 1P AND 19Q ANALYSIS:

FLUORESCENCE IN SITU HYBRIDIZATION (FISH) WAS PERFORMED ON REPRESENTATIVE PARAFFIN-EMBEDDED TUMOR TISSUE [REDACTED].

IN THIS CASE, NO DELETIONS OF 1P OR 19Q WERE IDENTIFIED.

[REDACTED]
[REDACTED]
[REDACTED]
REFERENCES:

Source: NCI Genomic Data Commons file 6144f5f3-173f-483d-82f9-005b793f0e2d (TCGA-DH-5143.5CEC11B4-9BA5-4A49-8C7C-6E9FDDE87C13.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).